Somatic mutation profile of tumor specimen MP2PRT-PASUIG-TMP1-A (aliquot MP2PRT-PASUIG-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PASUIG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,723 days).
Specimen MP2PRT-PASUIG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e89f5b9-0776-427a-9e46-d11d20c34b3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASUIG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASUIG-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad66083f-54a5-410d-80a2-76a0e9c9b9f2

The open-access MAF lists 647 somatic variants for this specimen: 463 protein-altering or splice-affecting, 163 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 429, Silent 163, Frame Shift Ins 19, Intron 10, Nonsense Mutation 4, 5'Flank 4, 3'UTR 4, Splice Site 3, Translation Start Site 3, Splice Region 2, Frame Shift Del 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 22/404 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2
- PMS2 | c.325dup p.E109Gfs*30 | Frame Shift Ins (INS) | VAF 130/316 reads (41%) | catalogued as rs587781716; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PYCR2 | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 96/290 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs886037932; ClinVar: pathogenic; called by muse, varscan2
- A2ML1 | c.2993T>C p.I998T | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1353986686; called by muse, mutect2
- ABCC1 | c.1601A>G p.E534G | Missense Mutation (SNP) | VAF 196/700 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as rs757239573; called by muse, varscan2
- AGMAT | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 35/506 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as rs200537622; called by muse, mutect2
- ALDOB | c.884C>A p.P295H | Missense Mutation (SNP) | VAF 128/485 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100878943; called by muse, mutect2, varscan2
- AMER1 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV57658107; called by muse, mutect2
- ANKRD24 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 22/746 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1320560344; called by muse, mutect2
- ATM | c.9079A>C p.S3027R | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763152094, COSV53786711; ClinVar: uncertain significance; called by muse, mutect2
- BLOC1S3 | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 40/932 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1238203980; called by muse, mutect2
- BRD1 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 40/656 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV53458006; called by muse, mutect2
- C4orf54 | c.1468dup p.L490Pfs*3 | Frame Shift Ins (INS) | VAF 206/778 reads (26%) | catalogued as rs775566152; called by mutect2, pindel, varscan2
- CA6 | c.284T>C p.M95T | Missense Mutation (SNP) | VAF 121/404 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761202224; called by muse, mutect2, varscan2
- CAPN15 | c.1873A>G p.I625V | Missense Mutation (SNP) | VAF 188/535 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs749479279; called by muse, mutect2, varscan2
- CDH3 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs761910448; called by muse, mutect2
- CELSR2 | c.8229G>T p.E2743D | Missense Mutation (SNP) | VAF 36/574 reads (6%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.952); catalogued as COSV54771656; called by muse, mutect2
- CEP43 | c.820A>G p.R274G | Missense Mutation (SNP) | VAF 23/360 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1342784735; called by muse, mutect2
- CREBBP | c.6178A>G p.R2060G | Missense Mutation (SNP) | VAF 204/619 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1461030167; called by muse, mutect2, varscan2
- CSNK2A3 | c.413A>G p.Y138C | Missense Mutation (SNP) | VAF 119/410 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs778507047; called by muse, mutect2
- CTC1 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 114/366 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs367666200; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLC1 | c.3185T>C p.M1062T (on ENST00000276297 / NM_001348081.2; = p.M625T on NM_006094.5) | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1484098903; called by muse, mutect2
- DYSF | c.2087T>C p.L696P | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs867390148; called by muse, mutect2, varscan2
- ELOA2 | c.856G>T p.G286W | Missense Mutation (SNP) | VAF 38/666 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs145748811; called by muse, mutect2
- FZD7 | c.1404G>T p.M468I | Missense Mutation (SNP) | VAF 40/676 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV53808960; called by muse, mutect2
- GLIS3 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780390959, COSV100174342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNAT3 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs186804021, COSV68067883; called by muse, mutect2, varscan2
- GPIHBP1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 42/603 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.292); catalogued as rs1260310518; called by muse, mutect2
- GRM8 | c.532T>C p.S178P | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1159093444; called by muse, mutect2, varscan2
- GYS1 | c.1747A>G p.I583V | Missense Mutation (SNP) | VAF 30/529 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs748757141; called by muse, mutect2
- HAUS5 | c.1880C>G p.A627G | Missense Mutation (SNP) | VAF 144/456 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1160606084; called by muse, mutect2, varscan2
- HCN4 | c.3313T>C p.S1105P | Missense Mutation (SNP) | VAF 21/790 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV56085765; called by muse, mutect2
- IFI16 | c.740C>A p.T247N | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV55536430; called by muse, mutect2, varscan2
- IFI6 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 275/850 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs1219713032; called by muse, mutect2, varscan2
- IGSF9B | c.2629T>C p.F877L | Missense Mutation (SNP) | VAF 215/762 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs1565425391; called by muse, mutect2, varscan2
- JAK3 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 16/363 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.053); catalogued as COSV71686560; called by muse, mutect2
- KALRN | c.3371G>A p.R1124Q | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs987606026, COSV53753292; called by muse, mutect2
- KCNK4 | c.969dup p.E324Rfs*104 | Frame Shift Ins (INS) | VAF 291/1079 reads (27%) | catalogued as rs775736273; called by mutect2, pindel, varscan2
- KCNQ1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 31/922 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.992); catalogued as rs533421208; called by muse, mutect2
- KIAA1109 | c.11599A>G p.S3867G | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1424394590; called by muse, mutect2
- LAMTOR2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 29/524 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs1395106562; called by muse, mutect2
- LCMT2 | c.728A>G p.H243R | Missense Mutation (SNP) | VAF 180/614 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs773762539; called by muse, mutect2
- LDLR | c.1792A>G p.I598V | Missense Mutation (SNP) | VAF 37/556 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as CM013578; called by muse, mutect2
- LRRC63 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as rs1415463225; called by muse, mutect2, varscan2
- MAGI2 | c.1839G>T p.Q613H | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV62643827; called by muse, mutect2
- MAP7D1 | c.844A>G p.S282G | Missense Mutation (SNP) | VAF 96/343 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs1314138973; called by muse, mutect2, varscan2
- MDH2 | c.890A>G p.K297R | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV59883723, COSV59884278; called by muse, mutect2
- METRN | c.622A>G p.I208V | Missense Mutation (SNP) | VAF 217/652 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.187); catalogued as rs1190630188; called by muse, mutect2, varscan2
- MGAT5B | c.1234T>C p.Y412H | Missense Mutation (SNP) | VAF 173/564 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.116); catalogued as rs778848821; called by muse, mutect2, varscan2
- MLANA | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1309315981; called by muse, mutect2
- MOV10L1 | c.2299A>G p.I767V | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs745658443; called by muse, mutect2
- MPZ | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 32/453 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV104414038; called by muse, mutect2
- MTSS1 | c.2192T>C p.M731T | Missense Mutation (SNP) | VAF 32/615 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV52674488; called by muse, mutect2
- MYO5B | c.87G>T p.K29N | Missense Mutation (SNP) | VAF 23/523 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV53229186; called by muse, mutect2
- MYOZ1 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 135/374 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63771785; called by muse, mutect2, varscan2
- NAA25 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 87/301 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.272); catalogued as rs1213846556; called by muse, mutect2, varscan2
- NABP2 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1292832369; called by muse, mutect2
- NDUFS1 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51907687, COSV51908938; called by muse, mutect2, varscan2
- NLRP1 | c.1748dup p.T584Dfs*7 | Frame Shift Ins (INS) | VAF 114/377 reads (30%) | catalogued as rs904995532; called by mutect2, varscan2
- NOL8 | c.682A>T p.S228C | Missense Mutation (SNP) | VAF 148/479 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV62635799; called by muse, mutect2, varscan2
- NOTCH1 | c.1729T>C p.Y577H | Missense Mutation (SNP) | VAF 188/618 reads (30%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.853); catalogued as rs865987089; called by muse, mutect2, varscan2
- OR5D16 | c.676A>G p.T226A | Missense Mutation (SNP) | VAF 16/545 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs981647723; called by muse, mutect2
- OR5T3 | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV57382521; called by muse, mutect2
- PALMD | c.1166A>G p.Q389R | Missense Mutation (SNP) | VAF 143/433 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.197); catalogued as COSV54167736; called by muse, mutect2, varscan2
- PAX5 | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 17/451 reads (4%) | catalogued as COSV63914939; called by muse, mutect2
- PIGR | c.2285A>G p.Q762R | Missense Mutation (SNP) | VAF 34/648 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62904790; called by muse, mutect2
- PKHD1 | c.2645T>C p.V882A | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs781231953; called by muse, mutect2
- PLXNA3 | c.1288A>G p.I430V | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782738193; called by muse, mutect2
- PROX2 | c.1562T>C p.L521P (on ENST00000556489 / NM_001243007.1; = p.L294P on NM_001080408.2) | Missense Mutation (SNP) | VAF 26/493 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101507805; called by muse, mutect2
- PSAP | c.1459A>G p.K487E | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1369232459; called by muse, mutect2, varscan2
- PSMA4 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as rs760080074; called by muse, mutect2
- PYROXD1 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 91/334 reads (27%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs142346936; called by muse, mutect2, varscan2
- RAB8A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99959837; called by muse, mutect2
- RIOK1 | c.677G>A p.G226E | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53571959; called by muse, mutect2, varscan2
- SPEN | c.5442G>T p.K1814N | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as COSV65362999; called by muse, mutect2
- SSH1 | c.1993A>G p.R665G | Missense Mutation (SNP) | VAF 170/580 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100425893; called by muse, mutect2, varscan2
- SUPT6H | c.2822A>G p.K941R | Missense Mutation (SNP) | VAF 31/480 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.048); catalogued as COSV58927425; called by muse, mutect2
- SYTL3 | c.291dup p.T98Dfs*25 | Frame Shift Ins (INS) | VAF 182/700 reads (26%) | catalogued as rs1356836335; called by mutect2, pindel, varscan2
- TBX4 | c.1631A>G p.D544G | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.721); catalogued as COSV99539799; called by muse, mutect2, varscan2
- TDRD15 | c.832T>C p.Y278H | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68267299; called by muse, mutect2
- TG | c.5039A>G p.K1680R | Missense Mutation (SNP) | VAF 78/288 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.106); catalogued as COSV55066620; called by muse, mutect2, varscan2
- TGDS | c.752C>A p.P251Q | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.356); catalogued as rs1043434770; called by muse, mutect2
- TNC | c.2916G>T p.K972N | Missense Mutation (SNP) | VAF 24/495 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV60789582; called by muse, mutect2
- TPM1 | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 15/476 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as rs1566937728; ClinVar: uncertain significance; called by muse, mutect2
- TREH | c.1411dup p.L471Pfs*34 | Frame Shift Ins (INS) | VAF 94/373 reads (25%) | catalogued as rs782422052; called by mutect2, pindel, varscan2
- TRIL | c.1181dup p.A395Gfs*12 | Frame Shift Ins (INS) | VAF 164/411 reads (40%) | catalogued as rs1308084701; called by mutect2, pindel, varscan2
- TRIM42 | c.2053A>G p.N685D | Missense Mutation (SNP) | VAF 35/391 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as COSV53886261; called by muse, mutect2
- UPF2 | c.101A>G p.K34R | Missense Mutation (SNP) | VAF 39/538 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs747907456; called by muse, mutect2
- VCPKMT | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 21/485 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1166147278; called by muse, mutect2
- VPREB3 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 15/426 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as rs867384221; called by muse, mutect2
- ZBED1 | c.1167C>A p.S389R | Missense Mutation (SNP) | VAF 266/882 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as COSV100586013; called by muse, varscan2
- ZC3H14 | c.1550A>G p.K517R | Missense Mutation (SNP) | VAF 95/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51773124; called by muse, mutect2, varscan2
- ZNF41 | c.1832A>G p.E611G | Missense Mutation (SNP) | VAF 28/289 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1354715553; called by muse, mutect2, varscan2
- ZNF48 | c.1757G>C p.R586P | Missense Mutation (SNP) | VAF 106/408 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV100198246, COSV60783064; called by muse, mutect2, varscan2
- ZNF526 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 22/636 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as rs1014885853; called by muse, mutect2
- ZNFX1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 71/275 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as rs765600865; called by muse, mutect2, varscan2
- ZRSR2 | c.1321A>G p.S441G | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV57066348; called by muse, mutect2, varscan2
- ZSCAN10 | c.1655A>G p.H552R (on ENST00000252463; = p.H607R on NM_032805.3) | Missense Mutation (SNP) | VAF 226/764 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs760578709; called by muse, mutect2, varscan2
- ABCA7 | c.4943A>G p.Y1648C | Missense Mutation (SNP) | VAF 28/614 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC006059.2 | c.2129A>G p.E710G | Missense Mutation (SNP) | VAF 61/632 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AC015802.6 | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- ACSBG1 | c.1339A>G p.K447E | Missense Mutation (SNP) | VAF 32/509 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ACSS2 | c.720-1G>T p.X240_splice | Splice Site (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- ACTN4 | c.2597A>G p.E866G | Missense Mutation (SNP) | VAF 32/566 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ADAMTS19 | c.1546T>C p.W516R | Missense Mutation (SNP) | VAF 71/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB2 | c.1908dup p.F637Lfs*62 | Frame Shift Ins (INS) | VAF 150/577 reads (26%) | called by mutect2, pindel, varscan2
- ADGRL3 | c.1307A>G p.D436G (on ENST00000506720 / NM_001322402.2; = p.D368G on NM_015236.6) | Missense Mutation (SNP) | VAF 38/380 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AGAP1 | c.2276A>G p.E759G (on ENST00000304032 / NM_001037131.3; = p.E706G on NM_014914.5) | Missense Mutation (SNP) | VAF 17/636 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- AGO2 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 23/415 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- AHSG | c.41G>T p.W14L | Missense Mutation (SNP) | VAF 31/502 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- AKAP6 | c.6724T>G p.L2242V | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); called by muse, mutect2
- ALOX12B | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 29/547 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ANK3 | c.269T>C p.V90A | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- AP4E1 | c.1615A>G p.K539E | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2
- APBA1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 33/537 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- APC | c.8502T>A p.H2834Q | Missense Mutation (SNP) | VAF 19/421 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARHGAP22 | c.689T>C p.L230P | Missense Mutation (SNP) | VAF 25/697 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP45 | c.667A>G p.M223V | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- ARHGEF17 | c.703T>C p.S235P | Missense Mutation (SNP) | VAF 232/676 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARID1B | c.2242G>T p.G748C | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARIH1 | c.1027-1G>T p.X343_splice | Splice Site (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- ARMH2 | c.395A>C p.N132T | Missense Mutation (SNP) | VAF 19/526 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ASH1L | c.7621A>C p.K2541Q (on ENST00000368346 / NM_001366177.2; = p.K2536Q on NM_018489.3) | Missense Mutation (SNP) | VAF 33/512 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- ATN1 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 35/674 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP11A | c.1030A>G p.K344E | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- ATP6V0A1 | c.2423T>C p.V808A (on ENST00000343619 / NM_001378531.1; = p.V802A on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- AUTS2 | c.2591A>C p.N864T | Missense Mutation (SNP) | VAF 155/278 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AVP | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 46/1066 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.052); called by muse, mutect2
- B3GALT4 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 280/877 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.891); called by muse, varscan2
- BAHCC1 | c.949T>C p.S317P | Missense Mutation (SNP) | VAF 36/990 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- BEND2 | c.2063T>G p.L688R | Missense Mutation (SNP) | VAF 27/312 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- BHLHE40 | c.787A>G p.S263G | Missense Mutation (SNP) | VAF 25/536 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.028); called by muse, mutect2
- BOLA1 | c.7A>G p.S3G | Missense Mutation (SNP) | VAF 21/573 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); called by muse, mutect2
- BRD8 | c.998T>C p.V333A (on ENST00000254900 / NM_139199.2; = p.V406A on NM_006696.4) | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.907); called by muse, mutect2
- BRPF3 | c.1900A>G p.M634V | Missense Mutation (SNP) | VAF 27/487 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- C18orf25 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 104/341 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- C1orf105 | c.20A>C p.K7T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC141 | c.2984A>G p.D995G | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.029); called by muse, mutect2
- CCDC168 | c.9781A>G p.S3261G | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2
- CCDC39 | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 25/558 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); called by muse, mutect2
- CCDC88C | c.5920A>G p.S1974G | Missense Mutation (SNP) | VAF 31/801 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- CDCP1 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDHR4 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 98/449 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- CDK10 | c.764T>C p.L255P (on ENST00000353379 / NM_052988.5; = p.L184P on NM_052987.4) | Missense Mutation (SNP) | VAF 116/451 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK5R1 | c.487T>C p.C163R | Missense Mutation (SNP) | VAF 21/792 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- CDKN2AIP | c.1310A>G p.Q437R | Missense Mutation (SNP) | VAF 105/358 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CDON | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEACAM5 | c.207A>C p.K69N | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- CEBPB | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 50/928 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEL | c.440T>C p.L147P (on ENST00000673714; = p.L144P on NM_001807.6) | Missense Mutation (SNP) | VAF 44/722 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- CELSR2 | c.2334A>C p.Q778H | Missense Mutation (SNP) | VAF 16/539 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- CENPS | c.338A>C p.Q113P | Missense Mutation (SNP) | VAF 136/450 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPT | c.1106A>G p.E369G | Missense Mutation (SNP) | VAF 48/826 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- CHRM3 | c.970T>C p.S324P | Missense Mutation (SNP) | VAF 29/461 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- CHRNB4 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- CHST11 | c.106A>G p.M36V | Missense Mutation (SNP) | VAF 13/392 reads (3%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- CIC | c.2732dup p.G913Wfs*18 | Frame Shift Ins (INS) | VAF 207/777 reads (27%) | called by mutect2, pindel, varscan2
- CIZ1 | c.2363A>G p.Y788C | Missense Mutation (SNP) | VAF 20/499 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- CIZ1 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.152); called by muse, mutect2
- CLIP1 | c.1160A>G p.E387G | Missense Mutation (SNP) | VAF 167/568 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CNGA2 | c.1528T>C p.Y510H | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- CNIH2 | c.263G>T p.W88L | Missense Mutation (SNP) | VAF 21/440 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- COL5A1 | c.5143T>C p.Y1715H | Missense Mutation (SNP) | VAF 14/439 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A2 | c.1972A>G p.T658A | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.026); called by muse, mutect2
- COL9A2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.023); called by muse, mutect2
- CPLANE1 | c.8900A>G p.Y2967C | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.982); called by muse, mutect2
- CRB2 | c.2491T>C p.C831R | Missense Mutation (SNP) | VAF 170/634 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CREBBP | c.5977A>G p.S1993G | Missense Mutation (SNP) | VAF 258/768 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBBP | c.5026T>C p.W1676R | Missense Mutation (SNP) | VAF 32/792 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- CSK | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.1270A>C p.S424R | Missense Mutation (SNP) | VAF 107/408 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSNK1G1 | c.976T>C p.Y326H | Missense Mutation (SNP) | VAF 102/324 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, varscan2
- CTIF | c.1581G>T p.E527D | Missense Mutation (SNP) | VAF 23/483 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CTNNB1 | c.2107C>A p.Q703K | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2
- CTU2 | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2
- CUL7 | c.3596A>C p.N1199T | Missense Mutation (SNP) | VAF 30/611 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.232); called by muse, mutect2
- CYP8B1 | c.839T>G p.L280R | Missense Mutation (SNP) | VAF 25/595 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DAOA | c.154A>G p.R52G | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DCAF7 | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 18/211 reads (9%) | called by muse, mutect2
- DDB1 | c.1874A>G p.D625G | Missense Mutation (SNP) | VAF 22/353 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- DEDD | c.955T>C p.*319Rext*86 | Nonstop Mutation (SNP) | VAF 20/309 reads (6%) | called by muse, mutect2
- DIS3 | c.685T>C p.S229P | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DLGAP2 | c.2752T>A p.S918T | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH1 | c.10262A>G p.K3421R | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- DNAH3 | c.7697T>G p.M2566R | Missense Mutation (SNP) | VAF 40/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DNAJC2 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- DOCK4 | c.4939T>C p.S1647P | Missense Mutation (SNP) | VAF 12/303 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- DRAP1 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- DYNC1H1 | c.6617A>G p.K2206R | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EBLN1 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 135/493 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ECE1 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 32/690 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, mutect2
- ECEL1 | c.32A>G p.Y11C | Missense Mutation (SNP) | VAF 126/445 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EFHC1 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2
- EHD3 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 53/371 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EHMT1 | c.956T>C p.I319T | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- EIF4A3 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 32/704 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2
- EP400 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 202/992 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, varscan2
- EP400 | c.1394T>C p.L465P | Missense Mutation (SNP) | VAF 124/367 reads (34%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- EP400 | c.7676C>T p.A2559V | Missense Mutation (SNP) | VAF 88/913 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.101); called by muse, mutect2
- EPB41 | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2
- EPHA5 | c.2327A>G p.Q776R | Missense Mutation (SNP) | VAF 24/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- EPHB1 | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 36/570 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2
- EPM2A | c.773A>G p.K258R | Missense Mutation (SNP) | VAF 177/574 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EPRS1 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ERICH1 | c.1109A>G p.E370G | Missense Mutation (SNP) | VAF 28/629 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2
- ETF1 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by muse, mutect2
- EVPL | c.5576T>G p.L1859R | Missense Mutation (SNP) | VAF 172/632 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXD2 | c.955A>G p.K319E (on ENST00000312994 / NM_001193362.1; = p.K194E on NM_018199.3) | Missense Mutation (SNP) | VAF 166/509 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- F5 | c.5338A>T p.K1780* | Nonsense Mutation (SNP) | VAF 26/380 reads (7%) | called by muse, mutect2
- FAM193A | c.1585A>C p.S529R | Missense Mutation (SNP) | VAF 104/365 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT2 | c.2990T>C p.L997P | Missense Mutation (SNP) | VAF 206/643 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXO3 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FCRLB | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 48/1031 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- FGFBP2 | c.596A>G p.K199R | Missense Mutation (SNP) | VAF 191/587 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGR | c.500C>G p.A167G | Missense Mutation (SNP) | VAF 125/440 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FNBP4 | c.1874A>G p.E625G | Missense Mutation (SNP) | VAF 108/408 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FOSL1 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 190/644 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FOXR2 | c.431A>G p.Q144R | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- FRMD4A | c.1930T>C p.C644R | Missense Mutation (SNP) | VAF 32/548 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.648); called by muse, mutect2
- FRMPD1 | c.1100A>C p.N367T | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- FURIN | c.1951T>C p.C651R | Missense Mutation (SNP) | VAF 221/683 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FYCO1 | c.4120T>C p.Y1374H | Missense Mutation (SNP) | VAF 33/687 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- FZD3 | c.1135C>A p.L379I | Missense Mutation (SNP) | VAF 18/479 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- G6PD | c.485T>C p.I162T | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRE | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 39/299 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- GLI3 | c.2938A>G p.S980G | Missense Mutation (SNP) | VAF 48/552 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2
- GLYR1 | c.574A>G p.M192V | Missense Mutation (SNP) | VAF 125/452 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA5 | c.830A>G p.D277G | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPR3 | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 46/916 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); called by muse, mutect2
- GRIN1 | c.1577A>G p.Y526C | Missense Mutation (SNP) | VAF 27/546 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- GTF2H1 | c.1051A>G p.R351G | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- GTF3C1 | c.5822A>C p.E1941A | Missense Mutation (SNP) | VAF 28/628 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.141); called by muse, mutect2
- GTF3C4 | c.1351A>G p.I451V | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- GUCY2D | c.1734G>T p.K578N | Missense Mutation (SNP) | VAF 24/504 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2
- HELQ | c.1825A>G p.K609E | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by muse, mutect2
- HERC1 | c.13418A>G p.Q4473R | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- HSBP1L1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 73/591 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- IFT81 | c.1867A>G p.K623E | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- IGFN1 | c.2444A>G p.E815G (on ENST00000295591 / NM_001367841.1; = p.E3272G on NM_001164586.2) | Missense Mutation (SNP) | VAF 31/656 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- IGHMBP2 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 19/555 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- IL12RB2 | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- IL1RAPL2 | c.1178A>G p.D393G | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- INO80 | c.872dup p.A292Gfs*3 | Frame Shift Ins (INS) | VAF 86/314 reads (27%) | called by mutect2, pindel, varscan2
- INSM1 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 58/1059 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.434); called by muse, mutect2
- IPO7 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2
- IRF2BP2 | c.1651A>G p.S551G | Missense Mutation (SNP) | VAF 31/482 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ITCH | c.2536A>G p.M846V (on ENST00000262650 / NM_001257137.3; = p.M805V on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ITGA5 | c.3011T>C p.L1004P | Missense Mutation (SNP) | VAF 28/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGAX | c.2542T>C p.C848R | Missense Mutation (SNP) | VAF 35/530 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITGB3 | c.809A>G p.H270R | Missense Mutation (SNP) | VAF 33/493 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- ITPR2 | c.4004T>C p.L1335S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- JAG1 | c.2132A>G p.E711G | Missense Mutation (SNP) | VAF 110/426 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KAT6A | c.5992A>G p.N1998D | Missense Mutation (SNP) | VAF 86/269 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KBTBD12 | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 110/325 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNA2 | c.1211T>C p.L404S | Missense Mutation (SNP) | VAF 29/591 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ14 | c.893A>G p.E298G | Missense Mutation (SNP) | VAF 41/633 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ16 | c.719T>C p.L240S | Missense Mutation (SNP) | VAF 148/465 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KCNQ2 | c.2057T>C p.I686T (on ENST00000359125 / NM_172107.4; = p.I658T on NM_004518.6) | Missense Mutation (SNP) | VAF 263/794 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- KIAA1109 | c.14486A>G p.E4829G | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIF1A | c.2108A>G p.E703G | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2
- KIF1B | c.4721T>C p.L1574P (on ENST00000377086 / NM_001365952.1; = p.L1528P on NM_015074.3) | Missense Mutation (SNP) | VAF 13/390 reads (3%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2
- KLHDC2 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.062); called by muse, varscan2
- KLHDC2 | c.724A>G p.M242V | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.147); called by muse, varscan2
- KLHDC9 | c.163A>G p.S55G | Missense Mutation (SNP) | VAF 51/910 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.303); called by muse, mutect2
- KLHL1 | c.1483A>G p.R495G | Missense Mutation (SNP) | VAF 29/489 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- KLHL40 | c.1760A>G p.N587S | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KMT2B | c.4048T>C p.Y1350H | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2D | c.3730dup p.V1244Gfs*6 | Frame Shift Ins (INS) | VAF 185/632 reads (29%) | called by mutect2, pindel, varscan2
- KRT12 | c.212dup p.G72Wfs*22 | Frame Shift Ins (INS) | VAF 194/825 reads (24%) | called by mutect2, pindel, varscan2
- KRTAP1-1 | c.163T>C p.C55R | Missense Mutation (SNP) | VAF 43/909 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- KRTAP4-16 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 138/494 reads (28%) | SIFT tolerated (0.08); called by muse, mutect2, varscan2
- KTN1 | c.2627T>C p.M876T | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2
- LILRA2 | c.1130A>G p.Q377R | Missense Mutation (SNP) | VAF 194/649 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- LIMK1 | c.1931A>G p.E644G | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- LRBA | c.6539T>C p.L2180P | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP2 | c.4348A>C p.S1450R | Missense Mutation (SNP) | VAF 33/454 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- LRRC8D | c.2567A>G p.N856S | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); called by muse, mutect2
- LTA4H | c.760T>C p.W254R | Missense Mutation (SNP) | VAF 119/377 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LY75 | c.2418A>G p.P806= | Splice Region (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- MAL2 | c.87del p.D30Tfs*44 | Frame Shift Del (DEL) | VAF 163/691 reads (24%) | called by mutect2, pindel, varscan2
- MAMSTR | c.1236G>T p.E412D (on ENST00000318083 / NM_001130915.2; = p.E309D on NM_182574.2) | Missense Mutation (SNP) | VAF 27/413 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- MAP3K19 | c.2219T>A p.I740N | Missense Mutation (SNP) | VAF 104/327 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAP3K7 | c.1028A>G p.D343G | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- MAPK8IP3 | c.2461T>C p.Y821H | Missense Mutation (SNP) | VAF 130/418 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCM6 | c.1117T>C p.F373L | Missense Mutation (SNP) | VAF 26/494 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.119); called by muse, mutect2
- MID1 | c.1580G>T p.S527I | Missense Mutation (SNP) | VAF 21/385 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.315); called by muse, mutect2
- MMP19 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP28 | c.1312T>C p.Y438H | Missense Mutation (SNP) | VAF 67/822 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- MMP9 | c.999T>C p.A333= | Splice Region (SNP) | VAF 118/375 reads (31%) | called by muse, mutect2, varscan2
- MOV10L1 | c.919T>G p.C307G | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MRPL20 | c.69G>T p.E23D | Missense Mutation (SNP) | VAF 30/628 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2
- MRPL4 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2
- MTMR14 | c.101A>G p.E34G | Missense Mutation (SNP) | VAF 64/875 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, mutect2
- MYH13 | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 92/308 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MYLK | c.1888T>G p.S630A | Missense Mutation (SNP) | VAF 24/479 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); called by muse, mutect2
- MYO7B | c.6299G>T p.S2100I | Missense Mutation (SNP) | VAF 38/712 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2
- MZF1 | c.440T>C p.M147T | Missense Mutation (SNP) | VAF 34/559 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- N4BP1 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAA16 | c.2163T>G p.N721K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- NAP1L3 | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- NBPF9 | c.2296T>C p.C766R | Missense Mutation (SNP) | VAF 16/566 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- NDN | c.323A>G p.Y108C | Missense Mutation (SNP) | VAF 21/472 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- NEDD9 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 125/447 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- NIN | c.5678A>G p.N1893S (on ENST00000382041 / NM_182946.1; = p.N1180S on NM_016350.4) | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- NIPBL | c.3814A>G p.N1272D | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- NOS1 | c.3148A>C p.N1050H | Missense Mutation (SNP) | VAF 230/663 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NOS2 | c.1468T>C p.Y490H | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); called by muse, mutect2
- NPAS2 | c.1481A>G p.Q494R | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2
- NPRL3 | c.1419C>A p.S473R (on ENST00000611875 / NM_001077350.3; = p.S448R on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.423); called by muse, mutect2
- NRIP1 | c.1312T>C p.C438R | Missense Mutation (SNP) | VAF 120/439 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRXN2 | c.4506C>A p.D1502E | Missense Mutation (SNP) | VAF 58/937 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2
- NSMCE3 | c.874A>G p.R292G | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- NUDT18 | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 34/682 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.025); called by muse, mutect2
- NUDT4 | c.137G>T p.W46L | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NYX | c.1000T>C p.F334L | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- OBSL1 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 28/1036 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.481); called by muse, mutect2
- OPN1SW | c.962A>G p.K321R | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OPRL1 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 64/1121 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- OR10V1 | c.65A>G p.E22G | Missense Mutation (SNP) | VAF 23/546 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- OR4K15 | c.372G>T p.Q124H (on ENST00000305051; = p.Q100H on NM_001005486.1) | Missense Mutation (SNP) | VAF 38/612 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- OSTF1 | c.153A>C p.K51N | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- OXA1L | c.367A>G p.S123G (on ENST00000285848; = p.S63G on NM_005015.5) | Missense Mutation (SNP) | VAF 19/587 reads (3%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- PADI3 | c.151T>A p.Y51N | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.871); called by muse, mutect2
- PAN2 | c.2369G>A p.G790E (on ENST00000425394 / NM_001127460.3; = p.G786E on NM_014871.5) | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PANK1 | c.1073T>C p.L358P (on ENST00000307534 / NM_148977.2; = p.L133P on NM_138316.4) | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARD6A | c.612G>T p.E204D | Missense Mutation (SNP) | VAF 28/672 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.083); called by muse, mutect2
- PARP15 | c.1289A>G p.D430G (on ENST00000464300 / NM_001113523.3; = p.D196G on NM_152615.2) | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PBRM1 | c.3386A>G p.K1129R (on ENST00000296302 / NM_001366071.2; = p.K1104R on NM_018313.5) | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- PCDHB11 | c.770T>A p.L257H | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDHGA12 | c.467A>G p.H156R | Missense Mutation (SNP) | VAF 124/404 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCLO | c.13053A>G p.I4351M | Missense Mutation (SNP) | VAF 108/194 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PDE3B | c.2021T>C p.M674T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- PDE6A | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PER3 | c.3421A>G p.R1141G | Missense Mutation (SNP) | VAF 107/450 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PGP | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 31/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PHC3 | c.1751T>C p.V584A (on ENST00000494943 / NM_001308116.2; = p.V596A on NM_024947.4) | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.446); called by muse, mutect2
- PHF5A | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 91/341 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PHLDB1 | c.3308A>G p.E1103G | Missense Mutation (SNP) | VAF 46/832 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- PIGS | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 29/574 reads (5%) | called by muse, mutect2
- PIK3CD | c.1330T>C p.S444P | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2
- PIK3CD | c.2699T>C p.M900T | Missense Mutation (SNP) | VAF 128/442 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITPNM2 | c.1723A>G p.N575D | Missense Mutation (SNP) | VAF 33/648 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2
- PITX3 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 34/457 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- PLCE1 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.102); called by muse, mutect2
- PLD3 | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 23/510 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.074); called by muse, mutect2
- PLXNC1 | c.3043T>C p.F1015L | Missense Mutation (SNP) | VAF 87/306 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLXND1 | c.3800dup p.S1268Qfs*34 | Frame Shift Ins (INS) | VAF 104/466 reads (22%) | called by mutect2, pindel, varscan2
- PLXND1 | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 270/870 reads (31%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PM20D2 | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, varscan2
- PML | c.607T>C p.Y203H | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PNLIPRP2 | c.569G>T p.R190M | Missense Mutation (SNP) | VAF 138/466 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLD4 | c.117dup p.D40Rfs*14 | Frame Shift Ins (INS) | VAF 168/574 reads (29%) | called by mutect2, varscan2
- POLR2B | c.395T>C p.V132A | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.155); called by muse, mutect2
- PPP1R14B | c.106dup p.A36Gfs*12 | Frame Shift Ins (INS) | VAF 197/789 reads (25%) | called by mutect2, pindel, varscan2
- PRMT2 | c.1207A>G p.R403G | Missense Mutation (SNP) | VAF 19/501 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PRPF4 | c.704A>G p.Y235C (on ENST00000374198 / NM_001322267.2; = p.Y236C on NM_004697.5) | Missense Mutation (SNP) | VAF 13/357 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PRPSAP2 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2
- PRSS57 | c.524T>C p.L175P | Missense Mutation (SNP) | VAF 55/858 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRUNE2 | c.1704G>T p.E568D | Missense Mutation (SNP) | VAF 48/527 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2
- PTPN13 | c.2304G>T p.K768N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PTPN13 | c.7037A>C p.Q2346P (on ENST00000411767 / NM_080683.3; = p.Q2327P on NM_006264.3) | Missense Mutation (SNP) | VAF 35/494 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2
- PTPRC | c.3859A>G p.T1287A | Missense Mutation (SNP) | VAF 25/545 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- PTPRQ | c.1684T>C p.Y562H (on ENST00000616559; = p.Y520H on NM_001145026.2) | Missense Mutation (SNP) | VAF 58/219 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PUM3 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PYGM | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAB27A | c.562T>C p.C188R | Missense Mutation (SNP) | VAF 109/455 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- RAD51AP2 | c.790dup p.M264Nfs*5 | Frame Shift Ins (INS) | VAF 102/344 reads (30%) | called by mutect2, pindel, varscan2
- RASGRP4 | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 162/513 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- RAVER1 | c.1490A>G p.Q497R (on ENST00000615032; = p.Q653R on NM_133452.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/512 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- RFX3 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 91/305 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RHEX | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 29/444 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); called by muse, mutect2
- RLF | c.880A>G p.T294A | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- RNASE11 | c.435A>G p.I145M | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.01); called by muse, mutect2
- RNF31 | c.2624A>G p.K875R | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.039); called by muse, mutect2
- ROBO2 | c.981A>C p.Q327H | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- RPL12 | c.191T>C p.I64T | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.261); called by muse, mutect2
- RPS16 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RUFY1 | c.1750G>T p.G584* | Nonsense Mutation (SNP) | VAF 113/416 reads (27%) | called by muse, mutect2, varscan2
- SART3 | c.1366T>C p.S456P (on ENST00000228284; = p.S438P on NM_014706.4) | Missense Mutation (SNP) | VAF 13/339 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.248); called by muse, mutect2
- SEC16B | c.1858A>C p.K620Q | Missense Mutation (SNP) | VAF 18/541 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2
- SELP | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 46/542 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- SEMA6C | c.2159A>G p.E720G | Missense Mutation (SNP) | VAF 34/803 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- SETD2 | c.5066T>C p.L1689P | Missense Mutation (SNP) | VAF 104/309 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SETD2 | c.4219del p.R1407Gfs*5 | Frame Shift Del (DEL) | VAF 98/400 reads (25%) | called by mutect2, pindel, varscan2
- SETD5 | c.1723A>G p.T575A | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- SH2D3C | c.1556G>T p.R519M (on ENST00000314830 / NM_170600.3; = p.R362M on NM_005489.4) | Missense Mutation (SNP) | VAF 20/692 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- SHANK1 | c.2192T>C p.V731A | Missense Mutation (SNP) | VAF 27/628 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- SIMC1 | c.2456A>C p.E819A (on ENST00000443967 / NM_001308196.1; = p.E404A on NM_198567.5) | Missense Mutation (SNP) | VAF 114/476 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SIPA1 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 159/537 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SLC22A15 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- SLC22A31 | c.769dup p.L257Pfs*33 | Frame Shift Ins (INS) | VAF 199/749 reads (27%) | called by mutect2, pindel, varscan2
- SLC26A6 | c.1646T>C p.V549A | Missense Mutation (SNP) | VAF 119/391 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- SLC2A10 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 49/664 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2
- SLC41A2 | c.1291A>G p.R431G | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- SLC4A5 | c.1504A>G p.I502V | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SNX8 | c.485A>C p.H162P | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SORBS1 | c.1625A>C p.K542T (on ENST00000361941 / NM_001034954.2; = p.K332T on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/324 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SORL1 | c.1624T>C p.W542R | Missense Mutation (SNP) | VAF 37/455 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SOX1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 184/639 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX21 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 48/622 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPEN | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 25/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SRCAP | c.1871T>C p.I624T | Missense Mutation (SNP) | VAF 129/364 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SRPK3 | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- STARD9 | c.11221A>G p.T3741A | Missense Mutation (SNP) | VAF 139/426 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK38 | c.536T>C p.M179T | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- STMN3 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 153/435 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRN3 | c.2147T>A p.I716N (on ENST00000357479 / NM_001083893.2; = p.I632N on NM_014574.4) | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TACC2 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- TACC3 | c.2466G>T p.E822D | Missense Mutation (SNP) | VAF 20/520 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2
- TAFA5 | c.106T>C p.Y36H | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.091); called by muse, mutect2
- TAPBPL | c.833A>G p.E278G | Missense Mutation (SNP) | VAF 36/632 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TAS1R1 | c.1919T>G p.L640R | Missense Mutation (SNP) | VAF 134/482 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- TAS2R19 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 18/560 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2
- TCHH | c.2327A>G p.K776R | Missense Mutation (SNP) | VAF 238/777 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TECTA | c.644A>C p.N215T | Missense Mutation (SNP) | VAF 19/387 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- TES | c.656T>C p.V219A | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM259 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 238/889 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TMEM63A | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 19/507 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- TMPRSS11E | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 21/511 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TMTC3 | c.2533A>C p.S845R | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2
- TNFRSF9 | c.128A>G p.Q43R | Missense Mutation (SNP) | VAF 94/317 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TNNC1 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 224/698 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOLLIP | c.551A>G p.Q184R | Missense Mutation (SNP) | VAF 20/616 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.073); called by muse, mutect2
- TOP2A | c.3818A>G p.K1273R | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TP53INP2 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2
- TPST2 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 37/600 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRAF7 | c.884A>G p.D295G | Missense Mutation (SNP) | VAF 23/603 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2
- TRAFD1 | c.766A>G p.S256G | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- TRAPPC13 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TRIM63 | c.970T>G p.F324V | Missense Mutation (SNP) | VAF 77/309 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRPM3 | c.3193A>G p.I1065V (on ENST00000357533 / NM_001366142.2; = p.I908V on NM_020952.6) | Missense Mutation (SNP) | VAF 26/576 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- TSPAN9 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC25 | c.1832T>A p.I611N | Missense Mutation (SNP) | VAF 22/536 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TTC37 | c.4053G>T p.K1351N | Missense Mutation (SNP) | VAF 61/228 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TTLL5 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 75/266 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- U2AF2 | c.32T>C p.L11P | Missense Mutation (SNP) | VAF 44/653 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- UBR4 | c.2896C>T p.L966F | Missense Mutation (SNP) | VAF 19/375 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2
- UBXN4 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- UMOD | c.1070T>C p.V357A | Missense Mutation (SNP) | VAF 25/643 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); called by muse, mutect2
- URAD | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 73/1035 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USF1 | c.482T>G p.F161C | Missense Mutation (SNP) | VAF 99/330 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USH2A | c.13702T>G p.F4568V | Missense Mutation (SNP) | VAF 20/285 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2
- USP40 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 26/571 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- VARS1 | c.553A>G p.N185D | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- VCAN | c.9734T>C p.L3245P | Missense Mutation (SNP) | VAF 18/313 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VEGFD | c.101A>G p.Q34R | Missense Mutation (SNP) | VAF 87/153 reads (57%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS52 | c.1289T>C p.L430P | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- WDR48 | c.361A>G p.K121E | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); called by muse, mutect2
- WFIKKN1 | c.955T>C p.Y319H | Missense Mutation (SNP) | VAF 42/920 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2
- WIZ | c.1037dup p.A347Cfs*17 | Frame Shift Ins (INS) | VAF 247/858 reads (29%) | called by mutect2, pindel, varscan2
- WTAP | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- XIRP1 | c.2549A>G p.D850G | Missense Mutation (SNP) | VAF 23/638 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.355); called by muse, mutect2
- XRN1 | c.3014G>C p.S1005T | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZC3H4 | c.2060dup p.I688Yfs*9 | Frame Shift Ins (INS) | VAF 120/407 reads (29%) | called by mutect2, pindel, varscan2
- ZFP30 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 11/295 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- ZHX1 | c.1235C>A p.P412H | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF182 | c.1916A>G p.H639R | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF225 | c.1309T>C p.Y437H | Missense Mutation (SNP) | VAF 166/503 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF45 | c.580T>C p.C194R | Missense Mutation (SNP) | VAF 22/462 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF587B | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.048); called by muse, mutect2
- ZNF623 | c.1544T>C p.L515S | Missense Mutation (SNP) | VAF 24/490 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- ZNF844 | c.1183A>G p.S395G | Missense Mutation (SNP) | VAF 21/284 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- ZSWIM8 | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 12/354 reads (3%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2
- ACAP2 | c.1356A>G p.R452= | Silent (SNP) | VAF 67/206 reads (33%) | called by muse, mutect2, varscan2
- ADGRB3 | c.927A>G p.Q309= | Silent (SNP) | VAF 30/430 reads (7%) | called by muse, mutect2
- ADGRG4 | c.1275T>G p.T425= | Silent (SNP) | VAF 12/335 reads (4%) | called by muse, mutect2
- ANK2 | c.2007C>A p.A669= | Silent (SNP) | VAF 28/554 reads (5%) | called by muse, mutect2
- AOC3 | c.372A>G p.A124= | Silent (SNP) | VAF 109/366 reads (30%) | called by muse, mutect2, varscan2
- APBA3 | c.636T>C p.H212= | Silent (SNP) | VAF 39/480 reads (8%) | catalogued as rs1025403589; called by muse, mutect2
- ARID1A | c.4155A>G p.E1385= | Silent (SNP) | VAF 32/637 reads (5%) | called by muse, mutect2
- ARNT | c.1923T>C p.P641= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- BCAS3 | c.249T>C p.H83= | Silent (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- BEST3 | c.27A>G p.V9= | Silent (SNP) | VAF 10/281 reads (4%) | catalogued as rs1303674303; called by muse, mutect2
- BLM | c.2121T>C p.P707= | Silent (SNP) | VAF 31/431 reads (7%) | called by muse, mutect2
- BRWD1 | c.2529T>C p.D843= | Silent (SNP) | VAF 88/314 reads (28%) | catalogued as rs754031672; called by muse, mutect2, varscan2
- BUD13 | c.228T>C p.D76= | Silent (SNP) | VAF 16/359 reads (4%) | called by muse, mutect2
- C2CD4C | c.441C>A p.S147= | Silent (SNP) | VAF 66/746 reads (9%) | called by muse, mutect2
- C3orf14 | c.102T>C p.G34= | Silent (SNP) | VAF 11/312 reads (4%) | called by muse, mutect2
- CAMK2D | c.348T>C p.C116= | Silent (SNP) | VAF 68/248 reads (27%) | catalogued as COSV99594427; called by muse, mutect2, varscan2
- CBX8 | c.807T>C p.A269= | Silent (SNP) | VAF 28/720 reads (4%) | called by muse, mutect2
- CCHCR1 | c.777T>C p.S259= | Silent (SNP) | VAF 40/473 reads (8%) | called by muse, mutect2
- CCT7 | c.1359T>G p.A453= | Silent (SNP) | VAF 26/401 reads (6%) | called by muse, mutect2
- CD1E | c.1086T>C p.H362= | Silent (SNP) | VAF 24/524 reads (5%) | called by muse, mutect2
- CD22 | c.1374C>A p.P458= | Silent (SNP) | VAF 36/576 reads (6%) | called by muse, mutect2
- CD300LD | c.48C>A p.S16= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- CDH17 | c.1503G>A p.G501= | Silent (SNP) | VAF 104/352 reads (30%) | catalogued as rs561736032, COSV50325649; called by muse, mutect2, varscan2
- CEL | c.1545T>C p.T515= (on ENST00000673714; = p.T512= on NM_001807.6) | Silent (SNP) | VAF 120/554 reads (22%) | called by muse, mutect2, varscan2
- CEP162 | c.294A>G p.L98= | Silent (SNP) | VAF 55/188 reads (29%) | called by muse, mutect2, varscan2
- CHD9 | c.7935A>T p.A2645= (on ENST00000398510 / NM_001382353.1; = p.A2629= on NM_025134.7) | Silent (SNP) | VAF 134/443 reads (30%) | catalogued as rs1378908463, COSV54608422; called by muse, mutect2, varscan2
- CHEK2 | c.240T>C p.P80= | Silent (SNP) | VAF 132/467 reads (28%) | called by muse, mutect2, varscan2
- CHST11 | c.654A>G p.K218= | Silent (SNP) | VAF 99/409 reads (24%) | called by muse, mutect2, varscan2
- CLVS2 | c.726T>C p.P242= | Silent (SNP) | VAF 43/482 reads (9%) | called by muse, mutect2
- COG5 | c.1281A>G p.Q427= | Silent (SNP) | VAF 15/197 reads (8%) | catalogued as rs1327142509, COSV99771802; called by muse, mutect2
- COL8A2 | c.378T>C p.G126= | Silent (SNP) | VAF 30/782 reads (4%) | called by muse, mutect2
- CRYBG1 | c.2781A>G p.E927= | Silent (SNP) | VAF 124/432 reads (29%) | called by muse, mutect2, varscan2
- CTCFL | c.1530A>G p.G510= | Silent (SNP) | VAF 21/450 reads (5%) | catalogued as COSV99713596; called by muse, mutect2
- CTRL | c.216T>C p.T72= | Silent (SNP) | VAF 18/462 reads (4%) | catalogued as rs1310709521; called by muse, mutect2
- DCAF10 | c.618T>G p.L206= | Silent (SNP) | VAF 27/304 reads (9%) | called by muse, mutect2
- DENND5B | c.1746A>G p.K582= | Silent (SNP) | VAF 29/353 reads (8%) | catalogued as rs768795568; called by muse, mutect2
- DHX9 | c.2007T>C p.H669= | Silent (SNP) | VAF 90/262 reads (34%) | called by muse, mutect2, varscan2
- DNAH5 | c.13626T>C p.G4542= | Silent (SNP) | VAF 123/488 reads (25%) | called by muse, mutect2, varscan2
- DNASE2 | c.807T>C p.D269= | Silent (SNP) | VAF 146/462 reads (32%) | called by muse, mutect2, varscan2
- DNHD1 | c.7629T>C p.I2543= | Silent (SNP) | VAF 45/443 reads (10%) | called by muse, mutect2, varscan2
- DNMT3B | c.1428T>C p.S476= | Silent (SNP) | VAF 124/419 reads (30%) | called by muse, mutect2, varscan2
- DPP9 | c.585T>C p.P195= (on ENST00000598800; = p.P224= on NM_139159.5) | Silent (SNP) | VAF 31/642 reads (5%) | called by muse, mutect2
- EGR1 | c.882C>A p.A294= | Silent (SNP) | VAF 171/640 reads (27%) | called by muse, mutect2, varscan2
- EIF2B4 | c.1524T>C p.P508= (on ENST00000347454 / NM_001034116.2; = p.P507= on NM_015636.3) | Silent (SNP) | VAF 126/398 reads (32%) | called by muse, varscan2
- ELF2 | c.279T>C p.D93= (on ENST00000379550 / NM_001331036.2; = p.D33= on NM_006874.4) | Silent (SNP) | VAF 11/340 reads (3%) | called by muse, mutect2
- FAT4 | c.6669T>C p.P2223= | Silent (SNP) | VAF 14/477 reads (3%) | called by muse, mutect2
- FAT4 | c.10848T>C p.S3616= | Silent (SNP) | VAF 114/370 reads (31%) | catalogued as COSV58688326; called by muse, mutect2, varscan2
- FRMD4A | c.2757G>T p.A919= | Silent (SNP) | VAF 254/824 reads (31%) | called by muse, mutect2, varscan2
- FTO | c.738T>C p.S246= | Silent (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- GALNT5 | c.1131A>G p.P377= | Silent (SNP) | VAF 28/356 reads (8%) | called by muse, mutect2
- GM2A | c.465T>C p.P155= | Silent (SNP) | VAF 118/382 reads (31%) | called by muse, varscan2
- GPANK1 | c.681T>C p.D227= | Silent (SNP) | VAF 44/888 reads (5%) | called by muse, mutect2
- GRIK5 | c.2614C>A p.R872= | Silent (SNP) | VAF 50/1018 reads (5%) | called by muse, mutect2
- GSTCD | c.1066T>C p.L356= (on ENST00000360505 / NM_001031720.3; = p.L269= on NM_024751.3) | Silent (SNP) | VAF 26/492 reads (5%) | called by muse, mutect2
- HERC1 | c.6753A>G p.S2251= | Silent (SNP) | VAF 141/448 reads (31%) | called by muse, mutect2, varscan2
- HOMER1 | c.351A>G p.S117= | Silent (SNP) | VAF 85/307 reads (28%) | catalogued as rs1465357950; called by muse, mutect2, varscan2
- HOXA4 | c.174C>A p.P58= | Silent (SNP) | VAF 265/510 reads (52%) | called by muse, mutect2, varscan2
- IGFBP2 | c.933T>C p.N311= | Silent (SNP) | VAF 135/502 reads (27%) | called by muse, mutect2, varscan2
- IGLV1-36 | c.36T>C p.T12= | Silent (SNP) | VAF 102/358 reads (28%) | called by muse, mutect2
- IKBIP | c.789A>G p.L263= | Silent (SNP) | VAF 22/450 reads (5%) | catalogued as COSV61081838; called by muse, mutect2
- IL17RD | c.1272A>G p.K424= | Silent (SNP) | VAF 142/505 reads (28%) | called by muse, mutect2, varscan2
- INTS7 | c.384T>C p.S128= | Silent (SNP) | VAF 62/193 reads (32%) | called by muse, mutect2, varscan2
- IQCF2 | c.495A>G p.*165= | Silent (SNP) | VAF 120/308 reads (39%) | called by muse, mutect2, varscan2
- KANK2 | c.1338A>G p.R446= | Silent (SNP) | VAF 213/716 reads (30%) | called by muse, mutect2, varscan2
- KIAA1109 | c.4410T>C p.G1470= | Silent (SNP) | VAF 104/358 reads (29%) | called by muse, mutect2, varscan2
- KLHL35 | c.1581T>G p.T527= | Silent (SNP) | VAF 22/394 reads (6%) | called by muse, mutect2
- LCOR | c.636T>C p.N212= | Silent (SNP) | VAF 20/485 reads (4%) | called by muse, mutect2
- LMAN2 | c.276T>C p.P92= | Silent (SNP) | VAF 122/357 reads (34%) | called by muse, mutect2, varscan2
- LRFN5 | c.1236T>C p.G412= | Silent (SNP) | VAF 76/300 reads (25%) | called by muse, mutect2, varscan2
- LRR1 | c.201G>A p.E67= | Silent (SNP) | VAF 123/359 reads (34%) | called by muse, mutect2, varscan2
- LRRC43 | c.1353T>C p.T451= | Silent (SNP) | VAF 24/429 reads (6%) | called by muse, mutect2
- MAGIX | c.447T>C p.T149= | Silent (SNP) | VAF 34/484 reads (7%) | called by muse, mutect2
- MAN2A2 | c.93C>T p.H31= | Silent (SNP) | VAF 129/465 reads (28%) | catalogued as rs1207368194, COSV64637362; called by muse, mutect2, varscan2
- MAN2B1 | c.2749T>C p.L917= | Silent (SNP) | VAF 27/664 reads (4%) | called by muse, mutect2
- MAP1B | c.5667T>C p.Y1889= | Silent (SNP) | VAF 34/364 reads (9%) | catalogued as COSV99702796; called by muse, mutect2
- MAPK6 | c.1089A>G p.S363= | Silent (SNP) | VAF 23/303 reads (8%) | called by muse, mutect2
- MARCHF7 | c.297T>C p.C99= | Silent (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- MAST2 | c.2355T>C p.F785= | Silent (SNP) | VAF 90/303 reads (30%) | called by muse, mutect2, varscan2
- MEAK7 | c.261C>A p.S87= | Silent (SNP) | VAF 144/464 reads (31%) | called by muse, mutect2, varscan2
- MFAP5 | c.417T>C p.L139= | Silent (SNP) | VAF 25/305 reads (8%) | called by muse, mutect2
- MSTO1 | c.873T>C p.T291= | Silent (SNP) | VAF 36/582 reads (6%) | called by muse, mutect2
- MTMR7 | c.66A>G p.K22= | Silent (SNP) | VAF 85/377 reads (23%) | catalogued as COSV51669386; called by muse, mutect2, varscan2
- MUC2 | c.2649C>A p.S883= | Silent (SNP) | VAF 13/367 reads (4%) | called by muse, mutect2
- N4BP2 | c.3312A>G p.L1104= | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV54703980; called by muse, mutect2
- NFKB2 | c.2136T>C p.D712= | Silent (SNP) | VAF 200/603 reads (33%) | called by muse, mutect2, varscan2
- NLRP9 | c.1383A>G p.R461= | Silent (SNP) | VAF 31/612 reads (5%) | called by muse, mutect2
- NME1-NME2 | c.828T>C p.P276= (on ENST00000555572; = p.P251= on NM_001018136.3) | Silent (SNP) | VAF 26/274 reads (9%) | called by muse, mutect2
- NOTCH3 | c.6429A>G p.P2143= | Silent (SNP) | VAF 32/1009 reads (3%) | catalogued as rs890365920; ClinVar: uncertain significance; called by muse, mutect2
- NOTCH3 | c.3285T>C p.H1095= | Silent (SNP) | VAF 39/758 reads (5%) | catalogued as COSV99659628; called by muse, mutect2
- NOTCH4 | c.444A>G p.G148= | Silent (SNP) | VAF 17/523 reads (3%) | called by muse, mutect2
- NSRP1 | c.1326A>G p.V442= | Silent (SNP) | VAF 15/285 reads (5%) | called by muse, mutect2
- NT5DC2 | c.1041A>G p.E347= | Silent (SNP) | VAF 28/452 reads (6%) | catalogued as COSV58741553; called by muse, mutect2
- NUP98 | c.2142A>G p.S714= | Silent (SNP) | VAF 41/480 reads (9%) | called by muse, mutect2
- ODF3L2 | c.243T>C p.P81= | Silent (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- PCLO | c.8166A>G p.Q2722= | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as rs1356468726; called by muse, mutect2
- PDE3A | c.3162C>A p.T1054= | Silent (SNP) | VAF 24/341 reads (7%) | catalogued as COSV62968193; called by muse, mutect2
- PHLPP1 | c.2058A>G p.E686= | Silent (SNP) | VAF 14/325 reads (4%) | catalogued as rs1222554679; called by muse, mutect2
- PITX1 | c.219A>G p.G73= | Silent (SNP) | VAF 40/842 reads (5%) | catalogued as COSV54761457; called by muse, mutect2
- PLEKHO2 | c.186T>C p.T62= | Silent (SNP) | VAF 18/289 reads (6%) | called by muse, mutect2
- PRDM4 | c.2382T>C p.D794= | Silent (SNP) | VAF 93/325 reads (29%) | called by muse, mutect2, varscan2
- PRPF31 | c.939A>G p.E313= | Silent (SNP) | VAF 30/554 reads (5%) | called by muse, mutect2
- PRRC2A | c.216T>C p.N72= | Silent (SNP) | VAF 209/703 reads (30%) | catalogued as rs1265673531; called by muse, mutect2, varscan2
- PRRC2A | c.2400C>A p.P800= | Silent (SNP) | VAF 54/938 reads (6%) | called by muse, mutect2
- RASGRP1 | c.1296C>T p.A432= | Silent (SNP) | VAF 87/278 reads (31%) | catalogued as rs777441111; called by muse, mutect2, varscan2
- RB1CC1 | c.2289A>G p.S763= | Silent (SNP) | VAF 72/272 reads (26%) | called by muse, mutect2, varscan2
- RBBP6 | c.1902A>G p.P634= | Silent (SNP) | VAF 89/363 reads (25%) | catalogued as COSV60508831; called by muse, mutect2, varscan2
- REST | c.3201T>C p.R1067= | Silent (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
- RFK | c.366T>C p.D122= | Silent (SNP) | VAF 11/185 reads (6%) | called by muse, mutect2
- RPLP2 | c.153T>C p.I51= | Silent (SNP) | VAF 126/427 reads (30%) | called by muse, mutect2, varscan2
- RTN3 | c.2160T>C p.S720= (on ENST00000377819 / NM_001265589.2; = p.S701= on NM_201428.3) | Silent (SNP) | VAF 15/364 reads (4%) | called by muse, mutect2
- SACS | c.4722T>C p.S1574= | Silent (SNP) | VAF 42/214 reads (20%) | called by muse, mutect2, varscan2
- SACS | c.2994T>C p.D998= | Silent (SNP) | VAF 93/270 reads (34%) | called by muse, mutect2, varscan2
- SATL1 | c.606A>C p.S202= (on ENST00000395409; = p.S389= on NM_001012980.2) | Silent (SNP) | VAF 42/281 reads (15%) | called by muse, mutect2, varscan2
- SCNN1D | c.6T>C p.A2= (on ENST00000338555; = p.L135P on NM_001130413.4) | Silent (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
- SEL1L2 | c.1593A>G p.K531= | Silent (SNP) | VAF 27/348 reads (8%) | catalogued as COSV53152265; called by muse, mutect2
- SEMA6C | c.1518T>C p.A506= | Silent (SNP) | VAF 29/727 reads (4%) | called by muse, mutect2
- SERINC3 | c.954T>C p.A318= | Silent (SNP) | VAF 130/443 reads (29%) | catalogued as rs757907913; called by muse, mutect2, varscan2
- SHOX2 | c.459T>C p.N153= (on ENST00000441443 / NM_006884.3; = p.N177= on NM_003030.4) | Silent (SNP) | VAF 48/626 reads (8%) | catalogued as COSV67464177; called by muse, mutect2
- SIPA1L1 | c.1212T>C p.D404= | Silent (SNP) | VAF 20/458 reads (4%) | called by muse, mutect2
- SKIDA1 | c.1299C>T p.A433= | Silent (SNP) | VAF 227/757 reads (30%) | catalogued as rs1273092046; called by muse, varscan2
- SLC30A7 | c.633A>G p.G211= | Silent (SNP) | VAF 26/406 reads (6%) | catalogued as rs1312896715; called by muse, mutect2
- SLC9A5 | c.2352T>C p.P784= | Silent (SNP) | VAF 56/638 reads (9%) | called by muse, mutect2
- SMAD9 | c.678A>G p.T226= | Silent (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- SP1 | c.1258T>C p.L420= (on ENST00000327443 / NM_138473.3; = p.L413= on NM_003109.1) | Silent (SNP) | VAF 29/669 reads (4%) | catalogued as COSV100540946; called by muse, mutect2
- SPATC1 | c.1074C>A p.A358= | Silent (SNP) | VAF 36/690 reads (5%) | catalogued as COSV66298423; called by muse, mutect2
- SPTBN2 | c.4938G>A p.Q1646= | Silent (SNP) | VAF 40/634 reads (6%) | called by muse, mutect2
- SRCAP | c.4083T>C p.A1361= | Silent (SNP) | VAF 172/606 reads (28%) | called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2964T>C p.H988= | Silent (SNP) | VAF 18/433 reads (4%) | called by muse, mutect2
- SUGP1 | c.1284T>C p.P428= | Silent (SNP) | VAF 20/521 reads (4%) | called by muse, mutect2
- TASOR2 | c.1272T>C p.P424= | Silent (SNP) | VAF 15/376 reads (4%) | called by muse, mutect2
- TATDN2 | c.534T>C p.L178= | Silent (SNP) | VAF 34/518 reads (7%) | called by muse, mutect2
- TBC1D1 | c.3201A>G p.E1067= | Silent (SNP) | VAF 83/311 reads (27%) | catalogued as rs770388959; called by muse, mutect2, varscan2
- TFAP4 | c.726T>C p.P242= | Silent (SNP) | VAF 89/326 reads (27%) | called by muse, mutect2, varscan2
- TGFBR2 | c.1152T>C p.N384= | Silent (SNP) | VAF 187/645 reads (29%) | catalogued as CM148046; called by muse, mutect2
- TH | c.141T>C p.P47= | Silent (SNP) | VAF 30/501 reads (6%) | called by muse, mutect2
- THADA | c.5728A>C p.R1910= | Silent (SNP) | VAF 17/612 reads (3%) | called by muse, mutect2
- THRAP3 | c.1248T>C p.D416= | Silent (SNP) | VAF 28/428 reads (7%) | called by muse, mutect2
- THRB | c.93A>G p.G31= | Silent (SNP) | VAF 17/553 reads (3%) | called by muse, mutect2
- TP53INP1 | c.177T>C p.P59= | Silent (SNP) | VAF 138/400 reads (35%) | catalogued as rs1199052823; called by muse, varscan2
- TREML1 | c.69T>C p.P23= | Silent (SNP) | VAF 18/530 reads (3%) | called by muse, mutect2
- TRIM26 | c.1539C>A p.T513= | Silent (SNP) | VAF 48/893 reads (5%) | called by muse, mutect2
- TRIP12 | c.1452T>C p.A484= | Silent (SNP) | VAF 19/284 reads (7%) | called by muse, mutect2
- TTBK2 | c.930T>C p.T310= | Silent (SNP) | VAF 34/609 reads (6%) | catalogued as rs1418953070; called by muse, mutect2
- TTN | c.82476T>C p.V27492= (on ENST00000591111; = p.V20068= on NM_003319.4) | Silent (SNP) | VAF 146/464 reads (31%) | catalogued as rs1002864801; called by muse, mutect2, varscan2
- WDR97 | c.3507T>C p.D1169= | Silent (SNP) | VAF 173/577 reads (30%) | catalogued as rs773027807; called by muse, mutect2, varscan2
- WIZ | c.5619T>G p.P1873= (on ENST00000673675 / NM_001371589.1; = p.P778= on NM_021241.3) | Silent (SNP) | VAF 32/779 reads (4%) | called by muse, mutect2
- WWC2 | c.2910A>G p.E970= | Silent (SNP) | VAF 18/384 reads (5%) | called by muse, mutect2
- YEATS2 | c.1128A>G p.V376= | Silent (SNP) | VAF 81/337 reads (24%) | called by muse, mutect2, varscan2
- ZBTB44 | c.675C>A p.S225= | Silent (SNP) | VAF 17/394 reads (4%) | catalogued as COSV63537498; called by muse, mutect2
- ZC3H11B | c.1029T>C p.N343= | Silent (SNP) | VAF 14/306 reads (5%) | called by muse, mutect2
- ZFAT | c.3246A>G p.E1082= | Silent (SNP) | VAF 13/367 reads (4%) | called by muse, mutect2
- ZFP62 | c.1938A>G p.E646= (on ENST00000502412 / NM_001377944.1; = p.E613= on NM_152283.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 58/478 reads (12%) | called by muse, mutect2, varscan2
- ZFYVE1 | c.69T>C p.A23= | Silent (SNP) | VAF 122/487 reads (25%) | called by muse, mutect2, varscan2
- ZIM3 | c.1158T>C p.T386= | Silent (SNP) | VAF 17/352 reads (5%) | called by muse, mutect2
- ZMYM1 | c.847T>C p.L283= | Silent (SNP) | VAF 99/342 reads (29%) | catalogued as rs1009591676; called by muse, mutect2, varscan2
- ZNF142 | c.3474A>G p.T1158= (on ENST00000411696 / NM_001379660.1; = p.T958= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 28/578 reads (5%) | called by muse, mutect2
- ZNF175 | c.2094T>C p.S698= | Silent (SNP) | VAF 11/313 reads (4%) | called by muse, mutect2
- ZNF501 | c.93T>C p.F31= | Silent (SNP) | VAF 21/414 reads (5%) | catalogued as COSV68516358; called by muse, mutect2
- ZNF585B | c.216A>G p.K72= | Silent (SNP) | VAF 28/324 reads (9%) | called by muse, mutect2
- ZNF587B | c.123T>A p.R41= | Silent (SNP) | VAF 41/456 reads (9%) | called by muse, mutect2
- ZNF598 | c.1233A>G p.V411= | Silent (SNP) | VAF 40/602 reads (7%) | catalogued as rs946933732; called by muse, mutect2
- ZNF805 | c.561A>G p.S187= | Silent (SNP) | VAF 90/350 reads (26%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.2163A>G p.P721= | Silent (SNP) | VAF 33/574 reads (6%) | called by muse, mutect2
- AL162417.1 | c.397-17024C>A | Intron (SNP) | VAF 32/712 reads (4%) | called by muse, mutect2
- ARHGAP26 | c.154+441C>A | Intron (SNP) | VAF 23/599 reads (4%) | called by muse, mutect2
- BRD3OS | chr9:134026881 T>C | 5'Flank (SNP) | VAF 29/631 reads (5%) | called by muse, mutect2
- C2orf16 | chr2:27574336 A>G | 5'Flank (SNP) | VAF 17/408 reads (4%) | called by muse, mutect2
- CCDC88B | c.*365A>G | 3'UTR (SNP) | VAF 108/413 reads (26%) | called by muse, mutect2, varscan2
- CXCR4 | c.16-20T>C | Intron (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- GANC | c.201+2455T>C | Intron (SNP) | VAF 28/464 reads (6%) | called by muse, mutect2
- ICOSLG | c.898+267A>G | Intron (SNP) | VAF 173/301 reads (57%) | called by muse, mutect2, varscan2
- INTS14 | c.-63+406A>G | Intron (SNP) | VAF 16/529 reads (3%) | called by muse, mutect2
- MYC | c.-188G>T | 5'UTR (SNP) | VAF 47/832 reads (6%) | catalogued as rs1388747184, COSV52368175, COSV52380282; called by muse, mutect2
- NOL12 | c.*1164T>C | 3'UTR (SNP) | VAF 24/487 reads (5%) | catalogued as rs1003980367; called by muse, mutect2
- RAB11FIP5 | c.1569-4531T>C | Intron (SNP) | VAF 154/456 reads (34%) | called by muse, mutect2, varscan2
- RNF212 | c.247-2852A>G | Intron (SNP) | VAF 31/545 reads (6%) | called by muse, mutect2
- RNU6-1191P | chr16:81109289 A>G | 5'Flank (SNP) | VAF 41/331 reads (12%) | catalogued as rs1291711856; called by muse, mutect2, varscan2
- RNU6-784P | chr4:70705273 A>G | 5'Flank (SNP) | VAF 38/769 reads (5%) | catalogued as rs977855064; called by muse, mutect2
- SPATA2L | c.*473T>C | 3'UTR (SNP) | VAF 29/691 reads (4%) | catalogued as rs1457057109; called by muse, mutect2
- STARD10 | c.*1G>T | 3'UTR (SNP) | VAF 34/548 reads (6%) | called by muse, mutect2
- STRA6 | c.-15-197T>G | Intron (SNP) | VAF 17/408 reads (4%) | called by muse, mutect2
- SYNPO | chr5:150656915 G>T | 3'Flank (SNP) | VAF 44/819 reads (5%) | called by muse, mutect2
- TRAK1 | c.287-16382C>A | Intron (SNP) | VAF 118/423 reads (28%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26674071 T>C | 3'Flank (SNP) | VAF 25/445 reads (6%) | called by muse, mutect2
